TCGA case TCGA-69-7974 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - Cleveland Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3e1df30f-744a-41e9-a169-7dbbff66622e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 54.8 years (20,021 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 33 days; Days to treatment end: 54 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed; Days to treatment start: 33 days; Days to treatment end: 96 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 75 days; Days to treatment end: 96 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 141 days; Treatment dose: 6,000 cGy; Treatment outcome: Treatment Ongoing; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Regional Site.

Follow-up (2 entries)
- Days to follow up: 184 days; Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests
- EGFR mutation, nos: Positive.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 58; FEV1 before bronchodilator (% of reference): 47.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1981; Tobacco smoking quit year: 2011.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-69-7974-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-69-7974-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 9; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-69-7974-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-69-7974-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung; EGFR mutation status: Yes; Pulmonary function test indicator: Yes.
- Drug treatment 2: Treatment best response: Clinical Progressive Disease.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 184 days; disease-specific survival: no event (censored), 184 days; progression-free interval: no event (censored), 184 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-69-7974-01A-11D-2183-01): tumor purity 0.29, ploidy 3.55, whole-genome doublings 2.
